Gene-level copy-number profile of tumor specimen HCM-BROD-0711-C64-01A from HCMI case HCM-BROD-0711-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 63.8 years (23,306 days).
Specimen HCM-BROD-0711-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7fa8db27-9690-4f44-b9fb-c7d9672f1d78.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0711-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/e58fe6e8-add6-4d67-af6d-080fcc05df45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 19,037; copy number 2: 37,967; copy number 3: 1,280; copy number 4: 18; copy number 5: 55.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr1:248,590,487–248,655,528, 6 genes: OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr2:130,073,535–130,129,222, 4 genes: POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr13:18,467,172–18,611,675, 5 genes: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388.
- chr21:9,975,017–10,137,004, 4 genes (within-gene range 0–1): CR382285.1, CR382285.2, CR382287.1, CDRT15P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,132,553–22,499,749, 53 genes, copy number 5: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr21:8,603,547–8,603,984, 1 gene, copy number 5: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 16,693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
